Gene-level copy-number profile of tumor specimen HCM-SANG-1306-C25-01A-01D-A80T-32 from HCMI case HCM-SANG-1306-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G3.
Specimen HCM-SANG-1306-C25-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6bf4bec7-3935-4b87-9e97-50e5898b69e0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1306-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/129d7a3a-7651-4e21-837c-5e4c479e6c7e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 12,890; copy number 2: 40,385; copy number 3: 4,923; copy number 4: 115; copy number 5: 37; copy number 7: 4; copy number 9: 43.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:141,787,815–141,788,640, 1 gene (within-gene range 0–2): TAS2R6P.
- chr11:31,432,401–31,509,645, 1 gene (within-gene range 0–2): IMMP1L.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 84 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,235,475–38,853,028, 77 genes, copy number 5–9 (broad region; genes not listed).
- chr17:62,282,702–62,453,385, 7 genes, copy number 5 (within-gene range 4–5): AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A.

Autosomal genes at a single copy (total copy number 1): 11,623. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
